Gene-level copy-number profile of tumor specimen TCGA-L5-A4OG-01A from TCGA case TCGA-L5-A4OG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 79.7 years (29,105 days).
Specimen TCGA-L5-A4OG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b4ef3bc1-9b25-42cb-bdb0-fca0b3530e87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OG-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b63bc5ca-2ae5-447c-ae18-e801791f46ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,114; copy number 2: 23,279; copy number 3: 18,830; copy number 4: 7,796; copy number 5: 4,945; copy number 6: 3,491; copy number 7: 37; copy number 8: 46; copy number 10: 3; copy number 12: 20; copy number 14: 25; copy number 15: 217; copy number 19: 6; copy number 39: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OG-01A-11D-A25X-01): tumor purity 0.44, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,682,996–90,683,123, 1 gene: AC093729.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,277 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,535,995–115,034,302, 12 genes, copy number 5–39: PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB.
- chr6:103,583,135–156,774,662, 810 genes, copy number 5 (broad region; genes not listed).
- chr6:156,776,360–156,780,455, 3 genes, copy number 5: AL355297.3, MIR4466, AL355297.1.
- chr7:70,972–113,087,778, 2,079 genes, copy number 5 (broad region; genes not listed).
- chr7:113,116,718–113,118,560, 1 gene, copy number 5: SMIM30.
- chr7:114,086,327–114,693,772, 1 gene, copy number 7 (within-gene range 3–7): FOXP2.
- chr7:114,414,244–116,159,896, 16 genes, copy number 7: AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC.
- chr8:98,102,344–104,256,094, 147 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 6 (broad region; genes not listed).
- chr17:45,168,800–48,817,214, 154 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:61,354,763–72,640,472, 269 genes, copy number 6–19 (within-gene range 2–19) (broad region; genes not listed).
- chr18:20,946,906–25,056,760, 93 genes, copy number 7–15 (broad region; genes not listed).
- chr19:47,349,315–58,605,223, 843 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,114. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
